Somatic mutation profile of tumor specimen MMRF_1491_1_BM_CD138pos (aliquot MMRF_1491_1_BM_CD138pos_T2_KAS5U_L02368) from MMRF case MMRF_1491, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.6 years (20,309 days).
Specimen MMRF_1491_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9445d45-1f65-4420-8d44-f44583b61df1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1491_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1491_1_PB_Whole_C3_KAS5U_L02376; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd95d784-7aeb-4c92-915a-ad7ec10254a6

The open-access MAF lists 292 somatic variants for this specimen: 106 protein-altering or splice-affecting, 33 silent, 153 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, 3'UTR 88, Intron 40, Silent 33, 5'UTR 14, Nonsense Mutation 9, Splice Region 5, RNA 4, 3'Flank 4, 5'Flank 3, Frame Shift Ins 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV54997519; called by muse, mutect2
- ADGB | c.4364C>T p.A1455V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1016243111; called by muse, mutect2, varscan2
- ATXN2L | c.2159G>A p.G720E | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs1019808198; called by muse, mutect2, varscan2
- BMP5 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 63/156 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs866769080, COSV100896355; called by muse, mutect2, varscan2
- CASR | c.2896G>A p.E966K (on ENST00000490131; = p.E1043K on NM_000388.4) | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.075); catalogued as COSV99064811, COSV99948463; called by muse, mutect2, varscan2
- CC2D1A | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 124/305 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs370809399; called by muse, mutect2, varscan2
- CCDC39 | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1216806909; called by muse, mutect2
- CDH1 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99931659; called by muse, mutect2, varscan2
- CERS4 | c.790C>G p.L264V | Missense Mutation (SNP) | VAF 94/181 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.163); catalogued as rs1202115771; called by muse, mutect2, varscan2
- CMYA5 | c.5756C>G p.S1919C | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV101483964; called by muse, mutect2, varscan2
- COL22A1 | c.4801C>A p.P1601T | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as COSV57348788; called by muse, mutect2, varscan2
- CTC1 | c.3484G>A p.E1162K | Missense Mutation (SNP) | VAF 59/61 reads (97%) | SIFT tolerated (0.07); PolyPhen benign (0.078); catalogued as COSV100236466; called by muse, mutect2, varscan2
- DCANP1 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 102/225 reads (45%) | catalogued as COSV104439640; called by muse, mutect2, varscan2
- DHRS3 | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.258); catalogued as rs878962021; called by muse, mutect2
- DICER1 | c.4018G>A p.E1340K | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58616074, COSV58627011; called by muse, mutect2
- FGFR2 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60641276; called by muse, mutect2
- GFI1B | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 43/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754439744, COSV59744470; called by muse, mutect2, varscan2
- GPR160 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100576172; called by muse, mutect2, varscan2
- HMCN1 | c.3286G>A p.E1096K | Missense Mutation (SNP) | VAF 59/90 reads (66%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs377574530; called by muse, mutect2, varscan2
- IGF2BP1 | c.1530G>A p.V510= | Splice Region (SNP) | VAF 48/77 reads (62%) | catalogued as rs1008328731; called by muse, mutect2, varscan2
- IGLL5 | c.88G>A p.G30S | Missense Mutation (SNP) | VAF 18/20 reads (90%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.284); catalogued as rs779042230, COSV104440278, COSV104440315; called by muse, varscan2
- IGLV3-25 | c.311A>T p.Y104F | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754192283; called by muse, mutect2, varscan2
- KDM5B | c.3484G>A p.A1162T | Missense Mutation (SNP) | VAF 82/138 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as rs151073190; called by muse, mutect2, varscan2
- LGR6 | c.2713C>T p.Q905* (on ENST00000367278 / NM_001017403.1; = p.Q853* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 7/176 reads (4%) | catalogued as COSV55154375; called by muse, mutect2
- LRP1B | c.2515G>A p.E839K | Missense Mutation (SNP) | VAF 59/126 reads (47%) | SIFT tolerated (0.41); PolyPhen benign (0.084); catalogued as COSV63341929; called by muse, mutect2, varscan2
- MCC | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs780983572, COSV56731413; called by muse, mutect2, varscan2
- NPAS4 | c.1988G>C p.G663A | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (1); PolyPhen possibly damaging (0.458); catalogued as COSV60652605; called by muse, mutect2, varscan2
- OR2A2 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as rs759840581, COSV68870991, COSV68871204; called by muse, mutect2, varscan2
- PLEKHG1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 99/208 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs372467316; called by muse, mutect2, varscan2
- PPP1CA | c.750G>A p.V250= | Splice Region (SNP) | VAF 44/115 reads (38%) | catalogued as rs1288805861; called by muse, mutect2, varscan2
- PRDM15 | c.2339-3C>T | Splice Region (SNP) | VAF 25/46 reads (54%) | catalogued as rs1354988283; called by muse, mutect2, varscan2
- RPS28 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 30/62 reads (48%) | catalogued as rs1391397858; called by muse, mutect2, varscan2
- RTL1 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 51/110 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.267); catalogued as rs781425496, COSV66016588; called by muse, mutect2, varscan2
- RTN2 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs762160784; called by muse, mutect2, varscan2
- SLC10A5 | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764319263; called by muse, mutect2
- SMC4 | c.2401G>A p.E801K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61007529; called by muse, mutect2
- TET1 | c.49G>A p.D17N | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV65390773; called by muse, mutect2, varscan2
- TMEM70 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100384214; called by muse, mutect2
- TP53 | c.150dup p.E51* | Frame Shift Ins (INS) | VAF 34/47 reads (72%) | catalogued as COSV52876575; called by mutect2, pindel, varscan2
- TSGA10IP | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56713032; called by muse, mutect2, varscan2
- TUBB6 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.577); catalogued as rs746302836, COSV99301405; called by muse, mutect2, varscan2
- USP34 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs1481663999; called by muse, varscan2
- VRTN | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV99832142; called by muse, mutect2, varscan2
- VWA3B | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374199782; called by muse, mutect2, varscan2
- WDR37 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54128390; called by muse, mutect2, varscan2
- ZNF420 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1232763762; called by muse, mutect2, varscan2
- ACVR1 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 98/174 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ADGB | c.4054C>T p.Q1352* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2
- AKAP9 | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- ANKRD30B | c.3835G>A p.E1279K | Missense Mutation (SNP) | VAF 54/163 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- ANKZF1 | c.14C>A p.P5Q | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- ANTXR2 | c.470C>T p.S157L | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- BEND2 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.135); called by muse, mutect2
- BNC2 | c.2017G>A p.D673N | Missense Mutation (SNP) | VAF 95/190 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRPF1 | c.1846A>G p.R616G | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- CCDC185 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- CD99 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 55/98 reads (56%) | called by muse, mutect2, varscan2
- CDH16 | c.1844G>A p.G615E | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP78 | c.131A>C p.D44A | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- COL24A1 | c.2077G>A p.G693R | Missense Mutation (SNP) | VAF 56/59 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CROT | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 90/179 reads (50%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- DCDC1 | c.214T>A p.Y72N | Missense Mutation (SNP) | VAF 9/246 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.122); called by muse, mutect2
- DNAJB7 | c.743C>T p.S248L | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DOCK10 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT tolerated (0.68); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- ENO4 | c.1040G>A p.G347E (on ENST00000622726; = p.G344E on NM_001242699.2) | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ERC1 | c.1411G>T p.V471L (on ENST00000360905 / NM_178040.4; = p.V443L on NM_178039.4) | Missense Mutation (SNP) | VAF 39/62 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- EZR | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 9/133 reads (7%) | called by muse, mutect2
- FAT4 | c.3163A>C p.K1055Q | Missense Mutation (SNP) | VAF 73/147 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GRB2 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GTDC1 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); called by muse, mutect2
- HMX3 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ISLR | c.310G>T p.D104Y | Missense Mutation (SNP) | VAF 123/258 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2E | c.1271G>A p.G424E | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LGALS9 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRGUK | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- LRRTM1 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- MDN1 | c.10894C>G p.L3632V | Missense Mutation (SNP) | VAF 50/59 reads (85%) | SIFT deleterious (0.03); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- NEK2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NF1 | c.7831dup p.T2611Nfs*2 (on ENST00000358273 / NM_001042492.3; = p.T2590Nfs*2 on NM_000267.3) | Frame Shift Ins (INS) | VAF 103/248 reads (42%) | called by mutect2, pindel, varscan2
- NUAK2 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 44/81 reads (54%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PCDHA11 | c.1135G>A p.G379S | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.802); called by muse, mutect2, varscan2
- PCNX3 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- PIGV | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 123/210 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RAB29 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 197/348 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RAI1 | c.5209G>A p.E1737K | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- RANBP17 | c.341T>G p.I114S | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- RMND1 | c.1310C>A p.T437N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by mutect2, varscan2
- RPS6 | c.497-3dup | Splice Region (INS) | VAF 28/67 reads (42%) | called by mutect2, pindel, varscan2
- SCAMP2 | c.54C>G p.F18L | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2
- SIM1 | c.2000C>T p.S667L | Missense Mutation (SNP) | VAF 49/78 reads (63%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- SLC15A2 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 60/117 reads (51%) | called by muse, mutect2, varscan2
- SLC27A3 | c.1655C>A p.T552K (on ENST00000271857; = p.T424K on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 147/209 reads (70%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SLC30A7 | c.652C>G p.H218D | Missense Mutation (SNP) | VAF 80/86 reads (93%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, varscan2
- SORCS3 | c.2619C>A p.S873R | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TGM1 | c.1990G>C p.A664P | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- TJP1 | c.3637C>T p.H1213Y | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2
- TMEM170A | c.348G>A p.M116I | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TRIM67 | c.334T>C p.Y112H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TRIM77 | c.675_677del p.L226del | In Frame Del (DEL) | VAF 59/166 reads (36%) | called by mutect2, pindel, varscan2
- UNC79 | c.3511G>A p.E1171K (on ENST00000393151 / NM_001346218.2; = p.E994K on NM_020818.5) | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- USP34 | c.2611G>A p.D871N | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, varscan2
- UTP6 | c.248A>G p.E83G | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- ZDHHC20 | c.1062G>T p.G354= | Splice Region (SNP) | VAF 46/49 reads (94%) | called by muse, mutect2, varscan2
- ZNF573 | c.1717C>T p.Q573* (on ENST00000536220 / NM_001172692.1; = p.Q515* on NM_152360.3) | Nonsense Mutation (SNP) | VAF 22/52 reads (42%) | called by muse, mutect2, varscan2
- ZNF787 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.677); called by muse, mutect2
- ZWILCH | c.1708A>T p.N570Y | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- AKAP6 | c.807C>T p.I269= | Silent (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- AMOTL2 | c.1365C>T p.A455= | Silent (SNP) | VAF 47/80 reads (59%) | catalogued as rs777388355; called by muse, mutect2, varscan2
- ATP10A | c.3588G>T p.S1196= | Silent (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- BARHL1 | c.969C>T p.A323= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- CACNG4 | c.672G>A p.A224= | Silent (SNP) | VAF 79/158 reads (50%) | catalogued as rs377684890; called by muse, mutect2, varscan2
- CAMSAP2 | c.576G>A p.L192= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as rs761068698; called by muse, mutect2, varscan2
- CAP2 | c.840C>T p.V280= | Silent (SNP) | VAF 4/79 reads (5%) | called by muse, mutect2
- CCDC54 | c.789C>T p.L263= | Silent (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- DYSF | c.4398C>T p.L1466= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as rs1476328093; ClinVar: likely benign; called by muse, mutect2
- ERCC2 | c.903G>A p.T301= | Silent (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2
- FBXW12 | c.537C>T p.D179= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs375801466; called by muse, mutect2, varscan2
- HIP1 | c.264C>T p.N88= | Silent (SNP) | VAF 53/128 reads (41%) | catalogued as rs200260342; called by muse, mutect2, varscan2
- IGHV2-70 | c.189G>A p.G63= | Silent (SNP) | VAF 41/87 reads (47%) | catalogued as rs112642180; called by muse, varscan2
- KCTD8 | c.330G>A p.L110= | Silent (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- KDM3A | c.114C>T p.V38= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV57223300; called by muse, mutect2, varscan2
- KLHDC7A | c.1764C>T p.D588= | Silent (SNP) | VAF 55/170 reads (32%) | catalogued as rs746194217, COSV101272811; called by muse, varscan2
- LARGE2 | c.30G>A p.L10= | Silent (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1335G>A p.V445= | Silent (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- PCDHGB4 | c.1005C>T p.V335= | Silent (SNP) | VAF 40/114 reads (35%) | called by muse, varscan2
- PLEC | c.7047G>A p.L2349= (on ENST00000322810 / NM_201380.4; = p.L2239= on NM_000445.5) | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs782196411, COSV100510055; called by muse, mutect2, varscan2
- RASGEF1C | c.756G>A p.V252= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs34070710; called by muse, mutect2, varscan2
- RASSF10 | c.981C>T p.D327= | Silent (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- SEC63 | c.258C>T p.F86= | Silent (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- SERPINA3 | c.198G>A p.L66= | Silent (SNP) | VAF 114/251 reads (45%) | called by muse, mutect2, varscan2
- SETD5 | c.3315C>T p.N1105= | Silent (SNP) | VAF 101/182 reads (55%) | catalogued as rs767871965; called by muse, mutect2, varscan2
- SIPA1L1 | c.4953C>T p.L1651= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- SLC24A4 | c.1410C>T p.I470= | Silent (SNP) | VAF 34/53 reads (64%) | called by muse, mutect2, varscan2
- TAF2 | c.3474G>A p.K1158= | Silent (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- TAS2R3 | c.462C>T p.L154= | Silent (SNP) | VAF 105/198 reads (53%) | catalogued as rs746632005; called by muse, mutect2, varscan2
- TBX1 | c.816G>A p.A272= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as rs758417980; called by muse, mutect2, varscan2
- TIMM44 | c.498C>T p.G166= | Silent (SNP) | VAF 55/161 reads (34%) | catalogued as rs780005890; called by muse, mutect2, varscan2
- TOR3A | c.864C>T p.L288= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as rs747436326; called by muse, mutect2
- ZNF16 | c.1260C>T p.L420= | Silent (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- ABLIM2 | chr4:7965838 C>T | 3'Flank (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- AC241952.1 | n.1247G>A | RNA (SNP) | VAF 108/138 reads (78%) | called by muse, mutect2, varscan2
- AMER3 | c.*3336G>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- ANO5 | c.*1165A>C | 3'UTR (SNP) | VAF 56/129 reads (43%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499145 T>A | 5'Flank (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- AP3B1 | c.*223C>T | 3'UTR (SNP) | VAF 38/63 reads (60%) | called by muse, mutect2, varscan2
- ARG1 | c.*173C>A | 3'UTR (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.384+8224C>T | Intron (SNP) | VAF 54/98 reads (55%) | called by muse, mutect2
- ARL1 | c.*1139C>T | 3'UTR (SNP) | VAF 53/53 reads (100%) | called by muse, mutect2, varscan2
- ARL14 | c.*212G>A | 3'UTR (SNP) | VAF 61/144 reads (42%) | called by muse, mutect2, varscan2
- ATP2C2 | c.515+77G>A | Intron (SNP) | VAF 3/16 reads (19%) | called by muse, mutect2
- ATP6V0B | c.116+117G>A | Intron (SNP) | VAF 30/44 reads (68%) | called by muse, mutect2, varscan2
- BACE1 | c.351-236G>A | Intron (SNP) | VAF 90/296 reads (30%) | called by muse, mutect2, varscan2
- BCL7C | c.*343G>A | 3'UTR (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- BEND4 | c.*3646G>C | 3'UTR (SNP) | VAF 47/108 reads (44%) | called by muse, mutect2, varscan2
- C16orf72 | c.*4555C>G | 3'UTR (SNP) | VAF 4/41 reads (10%) | called by muse, mutect2, varscan2
- C1D | c.*786C>T | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- C21orf58 | c.-801C>T | 5'UTR (SNP) | VAF 44/91 reads (48%) | called by muse, mutect2, varscan2
- C6orf120 | c.-212G>A | 5'UTR (SNP) | VAF 15/22 reads (68%) | called by muse, mutect2, varscan2
- C8orf33 | c.*206C>T | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- CALHM4 | chr6:116558596 C>A | 3'Flank (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- CBLB | c.*2277G>A | 3'UTR (SNP) | VAF 25/59 reads (42%) | called by muse, varscan2
- CCDC186 | c.*2475C>T | 3'UTR (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- CCM2 | c.*354C>T | 3'UTR (SNP) | VAF 10/122 reads (8%) | catalogued as rs1204231993; called by muse, mutect2
- CDH17 | c.*622C>G | 3'UTR (SNP) | VAF 48/49 reads (98%) | called by muse, mutect2, varscan2
- CDON | c.*1383C>T | 3'UTR (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2
- CHP2 | c.*243C>T | 3'UTR (SNP) | VAF 28/75 reads (37%) | catalogued as rs919219052; called by muse, mutect2
- CHST15 | c.*2202C>T | 3'UTR (SNP) | VAF 23/58 reads (40%) | catalogued as rs1211732795; called by muse, mutect2, varscan2
- CIBAR1 | c.261+684C>T | Intron (SNP) | VAF 26/26 reads (100%) | catalogued as rs895542705; called by muse, mutect2, varscan2
- CITED4 | c.*106G>A | 3'UTR (SNP) | VAF 13/13 reads (100%) | called by muse, mutect2, varscan2
- CLEC4D | c.*221A>T | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2, varscan2
- CLPP | c.555+153G>A | Intron (SNP) | VAF 9/19 reads (47%) | catalogued as rs1386793435; called by muse, mutect2, varscan2
- CNOT6L | c.*5658C>T | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- COL21A1 | c.*783C>T | 3'UTR (SNP) | VAF 8/145 reads (6%) | called by muse, mutect2
- COL22A1 | c.*646C>T | 3'UTR (SNP) | VAF 11/56 reads (20%) | called by muse, mutect2, varscan2
- COL6A1 | c.*611G>A | 3'UTR (SNP) | VAF 68/161 reads (42%) | called by muse, mutect2, varscan2
- CRLF3 | c.213-2858G>A | Intron (SNP) | VAF 49/103 reads (48%) | called by muse, mutect2, varscan2
- DCUN1D1 | c.*6254A>C | 3'UTR (SNP) | VAF 23/185 reads (12%) | called by muse, mutect2, varscan2
- DNAJC16 | c.*3095A>G | 3'UTR (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- DNMT3A | c.*398A>C | 3'UTR (SNP) | VAF 36/37 reads (97%) | called by muse, mutect2, varscan2
- DTNA | c.1662+2696C>T | Intron (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- EIF5 | c.*1640C>T | 3'UTR (SNP) | VAF 41/123 reads (33%) | called by muse, mutect2, varscan2
- ERP27 | c.577-32G>A | Intron (SNP) | VAF 13/16 reads (81%) | catalogued as COSV56762411; called by muse, mutect2, varscan2
- ESM1 | c.*1217G>A | 3'UTR (SNP) | VAF 23/108 reads (21%) | called by muse, mutect2, varscan2
- ESRRG | c.*648G>A | 3'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- ETNK2 | c.-140G>A | 5'UTR (SNP) | VAF 5/40 reads (13%) | catalogued as rs1052897428; called by muse, mutect2
- EXOC8 | c.*1584C>T | 3'UTR (SNP) | VAF 6/80 reads (8%) | catalogued as rs988905237; called by muse, mutect2
- FABP4 | c.*229G>A | 3'UTR (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- FBXW5 | c.*489C>T | 3'UTR (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- FEM1B | c.*1853C>T | 3'UTR (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- FGFR1OP2 | c.*1616C>A | 3'UTR (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- FLNA | c.7023+11G>A | Intron (SNP) | VAF 23/23 reads (100%) | catalogued as rs782097122; called by muse, mutect2, varscan2
- GALT | c.83-38G>A | Intron (SNP) | VAF 21/37 reads (57%) | called by muse, mutect2, varscan2
- GAP43 | c.31-12422C>T | Intron (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- GFER | c.259-115C>T | Intron (SNP) | VAF 17/24 reads (71%) | called by muse, mutect2, varscan2
- GLB1L3 | chr11:134274337 G>A | 5'Flank (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- GRM7 | c.737-87C>T | Intron (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- GSX1 | c.*595G>A | 3'UTR (SNP) | VAF 34/35 reads (97%) | called by muse, mutect2, varscan2
- GVQW3 | chr11:76381361 C>T | 5'Flank (SNP) | VAF 6/89 reads (7%) | called by muse, mutect2
- HEMK1 | c.*2790C>T | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- IRF1 | c.365-32G>A | Intron (SNP) | VAF 46/87 reads (53%) | catalogued as rs200597334; called by muse, mutect2, varscan2
- ISCA1 | c.242-1162T>C | Intron (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- ITGA1 | c.*3291C>T | 3'UTR (SNP) | VAF 55/91 reads (60%) | catalogued as rs550445755; called by muse, mutect2, varscan2
- KDSR | c.*2373G>A | 3'UTR (SNP) | VAF 54/180 reads (30%) | called by muse, mutect2, varscan2
- KIF13A | c.146+35695G>A | Intron (SNP) | VAF 17/33 reads (52%) | catalogued as rs374212698; called by muse, mutect2, varscan2
- KRTAP3-1 | c.*221G>C | 3'UTR (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- KRTCAP2 | c.4+13G>A | Intron (SNP) | VAF 51/76 reads (67%) | called by muse, mutect2, varscan2
- LHFPL1 | c.*80C>T | 3'UTR (SNP) | VAF 8/135 reads (6%) | catalogued as rs933191771; called by muse, mutect2
- LILRA5 | c.-76C>T | 5'UTR (SNP) | VAF 48/85 reads (56%) | called by muse, mutect2, varscan2
- LPAR3 | c.*597G>A | 3'UTR (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- LSMEM1 | c.128-698C>T | Intron (SNP) | VAF 15/40 reads (38%) | catalogued as rs1171120415; called by muse, mutect2
- MAP4 | chr3:47851482 C>T | 3'Flank (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- MAPK1IP1L | c.-44C>T | 5'UTR (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- MARCHF6 | c.-94G>A | 5'UTR (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- MMP16 | c.*7124G>A | 3'UTR (SNP) | VAF 34/41 reads (83%) | called by muse, mutect2, varscan2
- MRO | c.*2609C>T | 3'UTR (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- MROH9 | c.1734+763G>A | Intron (SNP) | VAF 83/207 reads (40%) | called by muse, mutect2, varscan2
- NCKAP5 | c.*637G>A | 3'UTR (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- NDRG4 | c.*605G>C | 3'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- NEK7 | c.*1458T>G | 3'UTR (SNP) | VAF 63/98 reads (64%) | called by muse, mutect2, varscan2
- NIBAN1 | c.*131G>A | 3'UTR (SNP) | VAF 12/282 reads (4%) | catalogued as rs1470657015; called by muse, mutect2
- OLFML2A | c.*1990C>T | 3'UTR (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- PAFAH1B2 | c.*2796C>T | 3'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- PAQR5 | c.*2637G>C | 3'UTR (SNP) | VAF 35/82 reads (43%) | called by muse, mutect2, varscan2
- PARP14 | c.*1941C>G | 3'UTR (SNP) | VAF 6/72 reads (8%) | catalogued as rs938983362; called by muse, mutect2
- PCDH12 | c.*478C>T | 3'UTR (SNP) | VAF 48/117 reads (41%) | called by muse, mutect2, varscan2
- PCDH18 | c.*1671A>C | 3'UTR (SNP) | VAF 28/65 reads (43%) | called by muse, mutect2, varscan2
- PCYT1B | c.*1011C>T | 3'UTR (SNP) | VAF 5/40 reads (13%) | catalogued as rs1314239671; called by muse, mutect2, varscan2
- PDLIM5 | c.921-7778C>T | Intron (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- PELI2 | c.-91G>A | 5'UTR (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- PIDD1 | c.1302+92C>T | Intron (SNP) | VAF 27/46 reads (59%) | called by muse, mutect2, varscan2
- PIK3C3 | c.*4250T>C | 3'UTR (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- PLA2R1 | c.*3019G>A | 3'UTR (SNP) | VAF 88/190 reads (46%) | called by muse, mutect2, varscan2
- PLAGL2 | c.*2487C>T | 3'UTR (SNP) | VAF 3/38 reads (8%) | catalogued as rs1486571728; called by muse, mutect2
- PLCB4 | c.*1060G>A | 3'UTR (SNP) | VAF 63/121 reads (52%) | called by muse, mutect2, varscan2
- PLK4 | c.*145G>A | 3'UTR (SNP) | VAF 35/102 reads (34%) | called by muse, mutect2, varscan2
- PLOD3 | c.1788+11G>A | Intron (SNP) | VAF 119/210 reads (57%) | called by muse, mutect2, varscan2
- PPP1CB | c.184+63G>T | Intron (SNP) | VAF 51/158 reads (32%) | called by muse, mutect2, varscan2
- PPP1R15B | c.*2041G>A | 3'UTR (SNP) | VAF 37/91 reads (41%) | catalogued as rs373598825; called by muse, mutect2, varscan2
- PRKRIP1 | c.*815G>A | 3'UTR (SNP) | VAF 51/116 reads (44%) | called by muse, mutect2, varscan2
- PRSS1 | c.201-24C>T | Intron (SNP) | VAF 33/154 reads (21%) | called by muse, mutect2, varscan2
- PTBP3 | chr9:112218518 C>T | 3'Flank (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- RASA4B | c.-1G>A | 5'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- RBM24 | c.169-19G>A | Intron (SNP) | VAF 105/216 reads (49%) | called by muse, mutect2, varscan2
- RBP1 | c.253-7202G>A | Intron (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- REEP5 | c.*2039G>A | 3'UTR (SNP) | VAF 46/136 reads (34%) | called by muse, mutect2, varscan2
- RHPN2P1 | n.2487T>A | RNA (SNP) | VAF 54/394 reads (14%) | called by muse, mutect2, varscan2
- RICTOR | c.*230G>T | 3'UTR (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- RIOK2 | c.1397+119G>A | Intron (SNP) | VAF 20/34 reads (59%) | catalogued as rs923502372; called by muse, mutect2, varscan2
- RNF185 | c.*2219C>G | 3'UTR (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- RORA | c.*6732G>A | 3'UTR (SNP) | VAF 10/54 reads (19%) | called by mutect2, varscan2
- SAXO2 | c.53+1868C>T | Intron (SNP) | VAF 21/84 reads (25%) | called by muse, mutect2
- SEC63 | c.*1816G>T | 3'UTR (SNP) | VAF 36/42 reads (86%) | called by muse, mutect2, varscan2
- SERPINE1 | c.*1652G>A | 3'UTR (SNP) | VAF 4/84 reads (5%) | called by muse, mutect2
- SFXN2 | c.*170G>C | 3'UTR (SNP) | VAF 40/75 reads (53%) | called by muse, mutect2, varscan2
- SLC1A2 | c.*7398G>C | 3'UTR (SNP) | VAF 6/66 reads (9%) | catalogued as COSV99554817; called by muse, mutect2
- SLC25A48 | c.813+1766A>G | Intron (SNP) | VAF 36/62 reads (58%) | called by muse, mutect2, varscan2
- SMARCB1 | c.363-46A>C | Intron (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- SNX21 | c.290-25G>A | Intron (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2
- SPATA18 | c.1479+80C>T | Intron (SNP) | VAF 32/72 reads (44%) | called by muse, mutect2, varscan2
- SPDL1 | c.*234G>A | 3'UTR (SNP) | VAF 35/105 reads (33%) | called by muse, mutect2, varscan2
- SRPX2 | c.*3719T>C | 3'UTR (SNP) | VAF 43/43 reads (100%) | called by muse, mutect2, varscan2
- SSU72 | c.224+899C>A | Intron (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- ST3GAL5 | c.*920G>A | 3'UTR (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- SUPT7L | c.*1272C>T | 3'UTR (SNP) | VAF 38/149 reads (26%) | catalogued as rs566289388; called by muse, mutect2, varscan2
- TEAD3 | c.*436G>A | 3'UTR (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2
- TEX9 | c.828+2702G>C | Intron (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- THSD7A | c.*1204G>A | 3'UTR (SNP) | VAF 6/95 reads (6%) | catalogued as rs902801236; called by muse, mutect2
- TLR4 | c.-9_-8del | 5'UTR (DEL) | VAF 49/173 reads (28%) | called by mutect2, pindel, varscan2
- TMEM243 | c.234+113C>T | Intron (SNP) | VAF 20/296 reads (7%) | called by muse, mutect2
- TMEM254 | c.87+42G>A | Intron (SNP) | VAF 58/115 reads (50%) | catalogued as rs760369724; called by muse, mutect2, varscan2
- TMEM78 | n.653T>G | RNA (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- TMF1 | c.*2998C>T | 3'UTR (SNP) | VAF 11/177 reads (6%) | called by muse, mutect2
- TNRC6B | c.3142-108A>G | Intron (SNP) | VAF 7/22 reads (32%) | called by muse, mutect2, varscan2
- TRAM2 | c.*5115_*5116del | 3'UTR (DEL) | VAF 68/119 reads (57%) | called by mutect2, varscan2
- TRIM11 | c.*583G>A | 3'UTR (SNP) | VAF 7/153 reads (5%) | called by muse, mutect2
- TSPAN17 | c.-146G>A | 5'UTR (SNP) | VAF 5/15 reads (33%) | catalogued as rs1009132767; called by muse, mutect2, varscan2
- TXNDC12 | c.-8C>T | 5'UTR (SNP) | VAF 14/56 reads (25%) | called by muse, mutect2
- UHRF1BP1 | c.*2022G>A | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- UMODL1 | c.1900-97C>T | Intron (SNP) | VAF 46/94 reads (49%) | catalogued as rs772778968; called by muse, mutect2, varscan2
- UNC80 | c.9059+495G>A | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- USP38 | c.*871T>C | 3'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- VAMP3 | c.*897G>A | 3'UTR (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- VASH1 | c.*1555G>A | 3'UTR (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- VENTX | c.*1412G>A | 3'UTR (SNP) | VAF 9/123 reads (7%) | called by muse, mutect2
- ZBTB7B | c.-203G>A | 5'UTR (SNP) | VAF 42/63 reads (67%) | called by muse, mutect2, varscan2
- ZC3H14 | c.*10341C>A | 3'UTR (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- ZNF33A | c.-127C>T | 5'UTR (SNP) | VAF 14/86 reads (16%) | called by muse, mutect2, varscan2
- ZNF415 | c.-162C>T | 5'UTR (SNP) | VAF 42/75 reads (56%) | called by muse, mutect2, varscan2
- ZNF417 | c.*586G>T | 3'UTR (SNP) | VAF 62/132 reads (47%) | called by muse, mutect2, varscan2
- ZNF510 | c.*1378G>A | 3'UTR (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2, varscan2
- ZNF658B | n.1293C>T | RNA (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- ZNF765 | c.*1322C>T | 3'UTR (SNP) | VAF 10/274 reads (4%) | called by muse, mutect2
